Somatic mutation profile of tumor specimen 0DU819 from CCDI case PBCKNX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Oligoastrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.3 years (1,935 days).
Specimen 0DU819: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b8d0bb1-8a9e-40ea-b811-b7fb87ad7425.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU80A (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cfbb01dd-2ea0-427f-9bc2-d9f99bd116d7

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 2, Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPC1 | c.2314A>G p.I772V | Missense Mutation (SNP) | VAF 226/884 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1185190060; called by muse, mutect2, varscan2
- LYPD4 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 231/2519 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as rs781913877; called by muse, mutect2
- TNFRSF8 | c.1032G>A p.A344= | Silent (SNP) | VAF 338/2131 reads (16%) | catalogued as rs374404049; called by muse, mutect2, varscan2
- CEP43 | c.301-89T>C | Intron (SNP) | VAF 24/466 reads (5%) | called by muse, mutect2
- CEP43 | c.301-88G>A | Intron (SNP) | VAF 24/481 reads (5%) | called by muse, mutect2
